Somatic mutation profile of tumor specimen TCGA-EL-A3D1-01A (aliquot TCGA-EL-A3D1-01A-11D-A19J-08) from TCGA case TCGA-EL-A3D1, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 39.0 years (14,245 days).
Specimen TCGA-EL-A3D1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7eaa5a09-359c-4291-90c7-a307a9e51103.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3D1-10A (Blood Derived Normal), aliquot TCGA-EL-A3D1-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3cd872c-3253-4e5b-b5be-955797463268

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/95 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- IL7R | c.1078A>G p.S360G | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV57412710; called by muse, mutect2, varscan2
- LYZ | c.170A>T p.N57I | Missense Mutation (SNP) | VAF 40/92 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV54261244; called by muse, mutect2, varscan2
- GIGYF1 | c.2126_2127del p.R709Pfs*111 | Frame Shift Del (DEL) | VAF 69/233 reads (30%) | called by pindel, varscan2
- ABCA2 | c.1375C>T p.L459= (on ENST00000614293; = p.L429= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as COSV55805984; called by muse, mutect2, varscan2
- PLS3 | c.733T>C p.L245= | Silent (SNP) | VAF 6/148 reads (4%) | catalogued as rs781934640; called by muse, mutect2
